Surgical pathology report (de-identified scan), TCGA case TCGA-XM-AAZ2, project TCGA-THYM (Thymoma), tissue source site MSKCC, specimen TCGA-XM-AAZ2-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: Thoracic
Account #: [REDACTED] Date of Procedure:
DOB: [REDACTED] M Date of Receipt:
Physician: [REDACTED] Date of Report:
CC: [REDACTED]

....

Clinical Diagnosis & History:
male with history of cough. Found to have an anterior
mediastinal mass. Biopsy showing thymoma.

Specimens Submitted:
1: Mediastinal tumor and pericardium
2: Mediastinal lymph node

DIAGNOSIS:
1. Mediastinal tumor and pericardium, excision:
- Thymoma, WHO Type A. (see note)
- The tumor measures 3.5 x 3 x 1.5cm
- The tumor is encapsulated
- Non neoplastic thymus is unremarkable
- The margins are free of tumor

Note: The tumor has focal B1-B2 areas; however, they comprise less than 10%
of the tumor

2. Mediastinal lymph node, excision:
- Three benign lymph nodes (0/3)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh and placed in formalin, labeled
"Mediastinal tumor and pericardium", and consists of a soft tissue resection
measuring 10 x 10 x 6 cm in overall dimension and weighing 364 g after
fixation. The attached pericardium is tan, smooth, ovoid in shaped and
measures 5 cm in diameter. There is an attached scant uninvolved adipose

** Continued on next page **

ICD-O-3
Thymoma, Type A NOS
8581/1
Site: anterior mediastinum
C38.1
JVO 3/12/14

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account #: [REDACTED]

Accession: [REDACTED]

Physician: [REDACTED]

Service: Thoracic

Date of Report: [REDACTED]

Page 2 of 2

tissue. The specimen was previously inked: green=resection margin; blue=pericardium; black=remaining specimen. Sectioning reveals a yellow-tan, lobular, homogenous, firm mass with a 3.5 x 3 x 1.5 cm cavity filled with clotted blood. Representative sections of the specimen are submitted. TPS and photo is taken.

Summary of sections:

TP - tumor with pericardium

TR - tumor with resection margin

TF - tumor with fat

TC - tumor with cavity

2). The specimen is received in formalin, labeled "Mediastinal lymph node" and consists of three firm tan lymph nodes ranging from 0.1 to 1.6 cm in greatest dimension. The lymph nodes are entirely submitted.

Summary of sections:

LN - lymph nodes

Summary of Sections:

Part 1: Mediastinal tumor and pericardium

Block	Sect.	Site	PCs
1		TC	1
3		TF	3
3		TP	3
3		TR	3

Part 2: Mediastinal lymph node

Block	Sect.	Site	PCs
2		LN	3

**** End of Report ****

Source: NCI Genomic Data Commons file 61373086-8f3b-4fb1-9aef-ebebeec96222 (TCGA-XM-AAZ2.63C3FEA5-DB7A-455F-9AD6-A6BC7B5B4195.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).